Somatic mutation profile of tumor specimen 0DNE0M from CCDI case PBCBMJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Choroid plexus carcinoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.3 years (830 days).
Specimen 0DNE0M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a92004c-3a56-4859-aec3-05d36938ae0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNE0R (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0749891e-49e4-4402-b2ab-c26cc531c915

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Frame Shift Del 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HGF | c.1361C>T p.T454M | Missense Mutation (SNP) | VAF 383/806 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764869064, COSV55945201, COSV55953678; called by muse, mutect2, varscan2
- NAGPA | c.1128C>G p.T376= | Splice Region (SNP) | VAF 249/672 reads (37%) | catalogued as COSV56569525; called by muse, mutect2, varscan2
- NIBAN2 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 450/483 reads (93%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); catalogued as rs1398722495; called by muse, mutect2, varscan2
- LYPD1 | c.317del p.C106Lfs*29 | Frame Shift Del (DEL) | VAF 368/537 reads (69%) | called by mutect2, pindel, varscan2
- MUSK | c.1676T>A p.L559H | Missense Mutation (SNP) | VAF 386/417 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKM | c.461A>G p.E154G | Missense Mutation (SNP) | VAF 429/904 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- TRIM24 | c.1814G>A p.G605D (on ENST00000343526 / NM_015905.3; = p.G571D on NM_003852.4) | Missense Mutation (SNP) | VAF 357/806 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- EMILIN2 | c.909C>T p.G303= | Silent (SNP) | VAF 317/349 reads (91%) | catalogued as rs942376364; called by muse, mutect2, varscan2
- OR1K1 | c.405G>A p.T135= | Silent (SNP) | VAF 15/296 reads (5%) | catalogued as rs1178960041; called by muse, mutect2
- WIPF3 | c.171T>C p.T57= | Silent (SNP) | VAF 26/782 reads (3%) | called by muse, mutect2
- CCT5 | c.*87dup | 3'UTR (INS) | VAF 71/102 reads (70%) | called by mutect2, pindel, varscan2
